Somatic mutation profile of tumor specimen TCGA-HT-A74H-01A (aliquot TCGA-HT-A74H-01A-11D-A32B-08) from TCGA case TCGA-HT-A74H, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 62.6 years (22,850 days).
Specimen TCGA-HT-A74H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58c96fd9-a0c8-4719-91ee-13adf2834529.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A74H-10A (Blood Derived Normal), aliquot TCGA-HT-A74H-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c8c29ac-532c-4515-ac5e-48c2247c015a

The open-access MAF lists 53 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 34, Silent 14, Frame Shift Del 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD3 | c.6463A>T p.N2155Y (on ENST00000297405 / NM_001363185.1; = p.N2051Y on NM_052900.3) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99835648; called by muse, mutect2, varscan2
- EPHA8 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs776940252, COSV99384917; called by muse, mutect2, varscan2
- ERN1 | c.1897A>C p.K633Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV101458450; called by muse, mutect2, varscan2
- FAT4 | c.7117A>G p.I2373V | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV100628767; called by muse, mutect2, varscan2
- FLG2 | c.4241C>A p.S1414Y | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV101165898; called by muse, mutect2, varscan2
- GHITM | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100930088; called by muse, mutect2, varscan2
- LAMB3 | c.3428G>A p.R1143H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs1313276336, COSV99151699; called by muse, mutect2, varscan2
- LRP1 | c.2230C>T p.H744Y | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV99675963; called by muse, mutect2, varscan2
- LRP2 | c.4562G>A p.R1521H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200469773; called by muse, mutect2, varscan2
- LTV1 | c.251C>A p.S84* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100849585; called by muse, mutect2, varscan2
- MAGEA10 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV99726735; called by muse, mutect2, varscan2
- MAGEE1 | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1556839632, COSV63910460; called by muse, mutect2, varscan2
- MUC17 | c.6335C>T p.T2112M | Missense Mutation (SNP) | VAF 48/396 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs138732859, COSV60280634; called by muse, mutect2, varscan2
- MYOCD | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs370289662; called by muse, mutect2, varscan2
- NEU2 | c.814T>G p.C272G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99290575; called by muse, mutect2
- NTN4 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.746); catalogued as COSV59219420; called by muse, mutect2, varscan2
- PCDHA7 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV65344513; called by muse, mutect2, varscan2
- PLXNA1 | c.5135C>T p.P1712L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1410617543, COSV99303180; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); catalogued as rs757901050, COSV53454130; called by muse, mutect2, varscan2
- PRB4 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs374921001, COSV54395119; called by muse, varscan2
- PRUNE2 | c.8231A>G p.E2744G | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100944643; called by muse, mutect2
- PRX | c.4207G>A p.V1403I | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.115); catalogued as rs139051512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RANBP17 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs201397836, COSV101206308; called by muse, mutect2, varscan2
- RYR2 | c.4990G>A p.V1664I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs749434532, COSV63698965, COSV63705585; called by muse, mutect2, varscan2
- SETD2 | c.4235_4238del p.E1412Vfs*19 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | catalogued as rs771527963; called by mutect2, pindel, varscan2
- SHROOM3 | c.2660G>A p.R887H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1052043657, COSV56027126; called by muse, mutect2
- SIAH3 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs752188051, COSV101247877; called by muse, mutect2, varscan2
- SLC13A2 | c.113G>A p.C38Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100120332; called by muse, mutect2, varscan2
- SLC2A13 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as rs758444290, COSV99786535; called by muse, mutect2, varscan2
- SLFN13 | c.2647A>T p.I883F | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV99540029; called by muse, mutect2, varscan2
- VCX3A | c.525T>A p.S175R | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs761292721, COSV101129898; called by muse, mutect2, varscan2
- ZNF460 | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100828084; called by muse, mutect2, varscan2
- ZNRF1 | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV100097135; called by muse, mutect2, varscan2
- ZPLD1 | c.803G>A p.R268Q (on ENST00000466937 / NM_001329788.1; = p.R284Q on NM_175056.2) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as rs764415767, COSV60354760; called by muse, mutect2, varscan2
- ATP8A1 | c.316_317del p.L106Ifs*16 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by pindel, varscan2
- PARP12 | c.1155del p.F385Lfs*16 | Frame Shift Del (DEL) | VAF 29/201 reads (14%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.869_872del p.I290Kfs*3 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- TRIT1 | c.561G>T p.R187S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VCX | c.585T>A p.S195R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, varscan2
- AHRR | c.375C>T p.V125= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs747226476, COSV100327367; called by muse, mutect2, varscan2
- ANKRD13C | c.681A>G p.L227= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV99257065; called by muse, mutect2, varscan2
- BAIAP2 | c.333G>A p.L111= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100348172; called by muse, mutect2, varscan2
- CLTCL1 | c.1902T>C p.Y634= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99595168; called by muse, mutect2, varscan2
- EXOC4 | c.1989G>A p.Q663= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs1372716529, COSV99554113; called by muse, mutect2, varscan2
- IKZF1 | c.1305C>T p.Y435= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV58783105; called by muse, mutect2, varscan2
- KRT27 | c.1323T>G p.T441= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs560769064, COSV100053279; called by muse, mutect2, varscan2
- MC2R | c.747C>A p.P249= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100563014; called by muse, mutect2, varscan2
- MC5R | c.519C>T p.C173= | Silent (SNP) | VAF 108/508 reads (21%) | catalogued as rs760716663, COSV61254939; called by muse, mutect2, varscan2
- NKX2-3 | c.93C>T p.H31= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- NLRP11 | c.2199C>T p.S733= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs116391886, COSV64086677; called by muse, mutect2
- NLRP7 | c.939G>A p.A313= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs534903397, COSV60176633; called by muse, mutect2, varscan2
- OSBPL9 | c.1983C>T p.N661= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs749050642, COSV100543453; called by muse, mutect2, varscan2
- TRAV26-1 | c.328G>A p.*110= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
